Somatic mutation profile of tumor specimen TCGA-D1-A1O8-01A (aliquot TCGA-D1-A1O8-01A-11D-A14G-09) from TCGA case TCGA-D1-A1O8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.6 years (25,789 days).
Specimen TCGA-D1-A1O8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc75e9f4-c36d-4122-8a00-5916b4c0d12d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1O8-10A (Blood Derived Normal), aliquot TCGA-D1-A1O8-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/353352ad-6fd6-4a1c-8206-e36ce0fd9aa3

The open-access MAF lists 72 somatic variants for this specimen: 50 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 21, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.5791C>T p.R1931* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as rs1028186690, COSV51647667; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.615_618del p.K206Pfs*15 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs1555534147; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1616C>G p.P539R | Missense Mutation (SNP) | VAF 16/46 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs121913285, COSV104381411, COSV55876380; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 23/104 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.778C>A p.H260N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.775); catalogued as COSV101000907; called by muse, mutect2, varscan2
- ANK3 | c.12436G>A p.G4146R (on ENST00000280772 / NM_001320874.2; = p.G667R on NM_001149.3) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184370155, COSV55046788; ClinVar: uncertain significance; called by muse, mutect2
- ARHGEF17 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs1307589484, COSV99735795; called by muse, mutect2, varscan2
- ARID1A | c.2623dup p.M875Nfs*61 | Frame Shift Ins (INS) | VAF 18/51 reads (35%) | catalogued as COSV61392138; called by mutect2, pindel, varscan2
- ATP1B4 | c.658T>A p.C220S (on ENST00000218008 / NM_001142447.3; = p.C216S on NM_012069.5) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs974267201, COSV99486393; called by muse, mutect2, varscan2
- CABP4 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs765171666, COSV56886126, COSV56886438; called by muse, mutect2, varscan2
- CDH10 | c.2081C>A p.T694K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.347); catalogued as COSV100051806, COSV52594816; called by muse, mutect2, varscan2
- COL14A1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.282); catalogued as rs1243045452, COSV99919509; called by muse, mutect2, varscan2
- COL1A2 | c.1280G>T p.G427V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99800017; called by muse, mutect2, varscan2
- COL5A3 | c.5051C>T p.T1684M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs770948835, COSV53406233, COSV53419886; called by muse, mutect2, varscan2
- CRAT | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748867542, COSV58876685; called by muse, mutect2, varscan2
- CREB5 | c.1214A>C p.K405T (on ENST00000357727 / NM_182898.4; = p.K398T on NM_004904.3) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100744835; called by muse, mutect2
- CSPG4 | c.5936A>G p.Y1979C | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100413821; called by muse, mutect2, varscan2
- CTNNBIP1 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV101032804; called by muse, varscan2
- CTNS | c.561+1G>T p.X187_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | catalogued as CD982567, COSV99251354; called by muse, mutect2, varscan2
- DIS3 | c.2832G>A p.M944I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100899917; called by muse, mutect2, varscan2
- DYRK1A | c.1560del p.T521Qfs*71 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | catalogued as COSV100117745; called by mutect2, pindel, varscan2
- F5 | c.3934C>T p.L1312F | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as COSV100889132; called by muse, mutect2, varscan2
- HRH2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1228318898, COSV51572722; called by muse, mutect2, varscan2
- INTS3 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100016115; called by muse, mutect2, varscan2
- LRRC75B | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99958995; called by muse, mutect2, varscan2
- MAGEE1 | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1556839945, COSV63909860; called by muse, mutect2, varscan2
- MYO18B | c.6716C>T p.S2239L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs192136611, COSV100123211, COSV59145660; called by muse, mutect2, varscan2
- MYO7B | c.3787G>C p.A1263P | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs192204741, COSV101268231; called by muse, mutect2, varscan2
- NBEA | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.508); catalogued as COSV100081075; called by muse, mutect2, varscan2
- NEK1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as rs969758381, COSV101455703; called by muse, mutect2, varscan2
- NOTCH1 | c.4012G>A p.A1338T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV99488760; called by muse, mutect2, varscan2
- NRXN3 | c.2204G>A p.R735H (on ENST00000335750 / NM_001330195.2; = p.R362H on NM_004796.6) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777228955, COSV59737828; called by muse, mutect2, varscan2
- NSD1 | c.5126G>T p.W1709L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100729312; called by muse, mutect2
- NSD1 | c.5147-1G>A p.X1716_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100729313; called by muse, mutect2
- OR10G4 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1420745750, COSV100304850; called by muse, varscan2
- OR51F1 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100598796, COSV58580491; called by muse, mutect2, varscan2
- PCDHA13 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1554174625, COSV56505136; called by muse, mutect2, varscan2
- POR | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV58693954; called by muse, mutect2, varscan2
- PTPRM | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.847); catalogued as COSV100157787; called by muse, mutect2, varscan2
- RIC8A | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs750588037, COSV57343692; called by muse, mutect2, varscan2
- SIGLEC10 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV100219100; called by muse, mutect2, varscan2
- SKP1 | c.382A>C p.K128Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100104528; called by muse, mutect2, varscan2
- SLC9C2 | c.2884G>C p.V962L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100876785, COSV62944215; called by muse, mutect2, varscan2
- SPTBN5 | c.9530C>T p.P3177L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); catalogued as COSV100311591; called by muse, mutect2, varscan2
- TACR2 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100066900; called by muse, mutect2, varscan2
- UBE2E3 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV101150424, COSV101150611; called by muse, mutect2, varscan2
- UBR2 | c.2297G>A p.S766N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100867461; called by muse, mutect2, varscan2
- PTEN | c.1012dup p.S338Ffs*5 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- ZBTB22 | c.1425del p.T477Lfs*28 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- ANKMY1 | c.1242C>T p.F414= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV56030100; called by muse, mutect2, varscan2
- ANTXR1 | c.399T>C p.Y133= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as rs755638121, COSV100362624; called by muse, mutect2, varscan2
- CDHR2 | c.933G>A p.A311= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs779101941, COSV99991708; called by muse, mutect2, varscan2
- DCAF12L1 | c.963C>T p.Y321= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV64422577; called by muse, mutect2, varscan2
- DZIP1L | c.393C>G p.R131= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV100551408; called by muse, mutect2, varscan2
- H1-2 | c.6C>G p.S2= | Silent (SNP) | VAF 51/140 reads (36%) | catalogued as rs764314267, COSV100642300, COSV59191954; called by muse, mutect2, varscan2
- HSPB9 | c.429G>A p.P143= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs933866650, COSV99863583; called by muse, mutect2, varscan2
- IRAG1 | c.108C>T p.D36= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs374994607; called by muse, mutect2, varscan2
- KCNH4 | c.1587C>T p.N529= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs765016708, COSV99237337; called by muse, mutect2, varscan2
- MAPK10 | c.852C>T p.S284= (on ENST00000359221 / NM_001351625.2; = p.S322= on NM_002753.5) | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs777934564, COSV100174620, COSV100174925; called by muse, mutect2, varscan2
- NCAM2 | c.1476G>A p.L492= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99520822, COSV99523378; called by muse, mutect2, varscan2
- NLRP14 | c.2877G>A p.L959= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100205427, COSV55063859; called by muse, mutect2, varscan2
- OLFML2A | c.1711C>A p.R571= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV56585775, COSV99992653; called by muse, mutect2, varscan2
- OR10V1 | c.921A>G p.R307= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100275976; called by muse, mutect2, varscan2
- PAN2 | c.522G>T p.L174= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99228322; called by muse, mutect2, varscan2
- PRKAG2 | c.1311C>G p.A437= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV99835422; called by muse, mutect2, varscan2
- SLC10A3 | c.1200C>G p.G400= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV99682142; called by muse, mutect2, varscan2
- SYNE2 | c.5310C>T p.A1770= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1245306266, COSV100647857; called by muse, mutect2
- TERT | c.978C>T p.A326= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs1435076658, COSV99717291, COSV99718769; called by muse, mutect2, varscan2
- TRIM42 | c.573C>T p.C191= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs143917166; called by muse, mutect2, varscan2
- ZNF423 | c.1323C>T p.H441= (on ENST00000563137 / NM_001379286.1; = p.H433= on NM_015069.4) | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs777932033, COSV52175395; called by muse, mutect2, varscan2
- MCF2 | chrX:139646887 G>T | 5'Flank (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100644828; called by muse, mutect2, varscan2
